Somatic mutation profile of tumor specimen TCGA-DD-AAVX-01A (aliquot TCGA-DD-AAVX-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVX, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 38.4 years (14,016 days).
Specimen TCGA-DD-AAVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c96aac-f523-412b-9199-554ba1681776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVX-10A (Blood Derived Normal), aliquot TCGA-DD-AAVX-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf2368d7-d8dc-4864-b0ff-397009442b73

The open-access MAF lists 83 somatic variants for this specimen: 57 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- AANAT | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166241; called by muse, mutect2, varscan2
- ACO1 | c.1739A>G p.K580R | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100008321; called by muse, mutect2, varscan2
- AHCTF1 | c.718A>G p.M240V (on ENST00000366508; = p.M214V on NM_015446.5) | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100404035; called by muse, mutect2, varscan2
- ALS2CL | c.1437-1G>T p.X479_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100015168; called by muse, mutect2, varscan2
- ARID1A | c.6073A>G p.K2025E | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100252317; called by muse, varscan2
- AVPR2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs1405690279, COSV100509574; called by muse, mutect2, varscan2
- BRINP3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66542068; called by muse, mutect2, varscan2
- CCDC66 | c.974A>C p.K325T (on ENST00000394672 / NM_001353147.1; = p.K291T on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100414118; called by muse, mutect2, varscan2
- CENPF | c.4704G>T p.E1568D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV65272586, COSV65275449; called by muse, mutect2, varscan2
- CFAP54 | c.6991A>T p.T2331S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100733269; called by muse, mutect2, varscan2
- COL3A1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1186071837, COSV58595248; called by muse, mutect2, varscan2
- CRISP1 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100236969; called by muse, mutect2, varscan2
- CSMD2 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs781533024, COSV53965954, COSV99592122; called by muse, mutect2, varscan2
- CYP2C8 | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV100987966; called by muse, mutect2, varscan2
- DENND5B | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs759799944, COSV100171750; called by muse, mutect2, varscan2
- ETV5 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100112423, COSV60502733; called by muse, mutect2, varscan2
- FRMPD2 | c.3099A>T p.R1033S | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100563962; called by muse, varscan2
- GPLD1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs758804691, COSV99219026; called by muse, mutect2, varscan2
- GYPA | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99302211; called by muse, mutect2, varscan2
- H2AC11 | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV100345818; called by muse, mutect2, varscan2
- HSF2 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV100869692; called by muse, mutect2, varscan2
- JAK1 | c.2185A>T p.S729C | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV61087444; called by muse, mutect2, varscan2
- JAML | c.1082A>G p.Y361C (on ENST00000356289 / NM_001098526.2; = p.Y351C on NM_153206.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99409614; called by muse, varscan2
- MKI67 | c.6787G>T p.G2263W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100896746; called by muse, mutect2, varscan2
- MPPED1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV101342250; called by muse, mutect2, varscan2
- NAB1 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.062); catalogued as COSV100493066; called by muse, mutect2, varscan2
- NCOA3 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100507796; called by muse, mutect2, varscan2
- NCOA3 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV100507797; called by muse, mutect2, varscan2
- NOTCH1 | c.5825A>T p.D1942V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99489584; called by muse, mutect2, varscan2
- NRG3 | c.2009G>T p.R670L (on ENST00000404547 / NM_001370084.1; = p.R646L on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs150401464, COSV100932179; called by muse, mutect2, varscan2
- NTN4 | c.1414T>C p.Y472H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100643802; called by muse, mutect2, varscan2
- NTN4 | c.1413G>C p.W471C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.428); catalogued as COSV100643807; called by muse, mutect2, varscan2
- OBSCN | c.18241G>T p.D6081Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99481207; called by muse, mutect2, varscan2
- OR2L8 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV100594255; called by muse, mutect2, varscan2
- PANX3 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99421618; called by muse, mutect2, varscan2
- PCDHGB3 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53947247, COSV99541757; called by muse, mutect2, varscan2
- PLXNA3 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV100860080; called by muse, mutect2, varscan2
- POU2AF1 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV101260662; called by muse, mutect2, varscan2
- PRPF40A | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100582936; called by muse, mutect2, varscan2
- PXT1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs760932663, COSV100339252; called by muse, mutect2, varscan2
- RXFP1 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100313924; called by muse, mutect2, varscan2
- SLC2A10 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs770142771, COSV100826384; called by muse, mutect2, varscan2
- SMYD3 | c.1219G>A p.E407K (on ENST00000490107 / NM_001375962.1; = p.E348K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100830799, COSV63628030; called by muse, mutect2, varscan2
- TBC1D12 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99831593; called by muse, mutect2, varscan2
- TONSL | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV68047575; called by muse, mutect2, varscan2
- TSGA10IP | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV101598415; called by muse, mutect2
- WNK3 | c.1577T>C p.L526S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100671039; called by muse, mutect2, varscan2
- ZC3H13 | c.3974G>T p.R1325L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.982); catalogued as COSV99668512; called by muse, mutect2, varscan2
- ZNF280B | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100840364; called by muse, mutect2, varscan2
- ZNF608 | c.4033T>A p.Y1345N | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100102042; called by muse, mutect2, varscan2
- ZNF608 | c.4032G>T p.Q1344H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs1482565737, COSV100102044; called by muse, mutect2, varscan2
- ZNF768 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.1); catalogued as rs1230317892, COSV100776287; called by muse, mutect2, varscan2
- ARID1A | c.6098del p.K2033Rfs*9 | Frame Shift Del (DEL) | VAF 60/125 reads (48%) | called by pindel, varscan2
- ASH1L | c.2721_2730dup p.A911Tfs*10 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- YLPM1 | c.1603_1611del p.P535_V537del | In Frame Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- ZFP64 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC142 | c.159G>A p.G53= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1231626111, COSV99282249; called by muse, mutect2, varscan2
- CEP170B | c.4251C>T p.D1417= (on ENST00000453495; = p.D1346= on NM_015005.3) | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs768674837, COSV99229857; called by muse, mutect2, varscan2
- DIXDC1 | c.1074G>T p.L358= (on ENST00000440460 / NM_001037954.4; = p.L147= on NM_033425.4) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100180324; called by muse, mutect2, varscan2
- GRB14 | c.636A>T p.A212= | Silent (SNP) | VAF 91/302 reads (30%) | catalogued as COSV99814223; called by muse, mutect2, varscan2
- IGFBP1 | c.525C>G p.P175= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV51874744, COSV99298784; called by muse, mutect2, varscan2
- KRT81 | c.1102C>T p.L368= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs773229998, COSV59809374; called by muse, mutect2, varscan2
- LHX8 | c.207T>A p.P69= | Silent (SNP) | VAF 68/149 reads (46%) | catalogued as COSV99633999; called by muse, mutect2, varscan2
- MASTL | c.603A>G p.R201= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs1345369865, COSV100668911; called by muse, mutect2, varscan2
- NRM | c.729G>T p.R243= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99223782; called by muse, mutect2, varscan2
- PDP1 | c.1422G>A p.E474= | Silent (SNP) | VAF 70/118 reads (59%) | catalogued as COSV99892625; called by muse, mutect2, varscan2
- PM20D2 | c.348G>A p.A116= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1345640273, COSV99248413; called by muse, mutect2
- PRDM9 | c.804G>T p.P268= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs569308746, COSV57002790, COSV99690020; called by muse, mutect2, varscan2
- SEPTIN5 | c.474C>T p.Y158= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1373911185, COSV100820417; called by muse, mutect2, varscan2
- SIGLEC9 | c.789A>G p.P263= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99142789; called by muse, mutect2, varscan2
- SLC34A2 | c.1392C>G p.G464= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV101158407, COSV65943038; called by muse, mutect2, varscan2
- SPOP | c.210A>T p.R70= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100753459; called by muse, mutect2, varscan2
- TDRD5 | c.2436A>G p.P812= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs147178825; called by muse, mutect2, varscan2
- TNXB | c.6400T>C p.L2134= (on ENST00000647633; = p.L1887= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs763294732, COSV100926438; called by muse, mutect2, varscan2
- TRIM56 | c.1003C>T p.L335= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100047485; called by muse, mutect2, varscan2
- UNC13C | c.3360C>T p.G1120= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV99519907; called by muse, mutect2, varscan2
- VGLL2 | c.87A>C p.L29= | Silent (SNP) | VAF 54/153 reads (35%) | catalogued as COSV100409958; called by muse, mutect2, varscan2
- ZFYVE27 | c.576A>T p.T192= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100519332; called by muse, mutect2, varscan2
- ZNF140 | c.951T>G p.T317= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100166848; called by muse, mutect2, varscan2
- ZNF808 | c.2193T>A p.G731= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100708065; called by muse, mutect2, varscan2
- ZZEF1 | c.897G>A p.R299= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101067910; called by muse, mutect2, varscan2
- RUSC1 | c.-86-272G>C | Intron (SNP) | VAF 37/104 reads (36%) | catalogued as COSV99430045; called by muse, mutect2, varscan2
